Somatic mutation profile of tumor specimen MP2PRT-PAVCSV-TMP1-A (aliquot MP2PRT-PAVCSV-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVCSV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.0 years (722 days).
Specimen MP2PRT-PAVCSV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2de7ec23-b030-4ea9-9c35-ef477afa830f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVCSV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVCSV-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cd3187d-84aa-4482-9553-75a2f94cb367

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 12, Nonsense Mutation 4, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF4 | c.3484A>T p.I1162L | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1443941113; called by muse, mutect2, varscan2
- ETV6 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 27/494 reads (5%) | catalogued as COSV67148006, COSV67150821; called by muse, mutect2
- IL1RAP | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1259485877; called by muse, mutect2
- MAIP1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1331700006; called by muse, mutect2, varscan2
- MYH7 | c.1178C>A p.A393D | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as CM137780; called by muse, mutect2
- ADAM22 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- CFAP74 | c.3155C>G p.S1052* | Nonsense Mutation (SNP) | VAF 52/532 reads (10%) | called by muse, mutect2
- CHM | c.833G>C p.R278T | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DDX60L | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.06); called by muse, mutect2
- GART | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- KDM5C | c.4106C>G p.S1369* | Nonsense Mutation (SNP) | VAF 17/501 reads (3%) | called by muse, mutect2
- N4BP2L2 | c.2149G>T p.D717Y (on ENST00000674422; = p.D288Y on NM_033111.4) | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- PDE6B | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 157/503 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- REXO2 | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 38/616 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2
- ROR1 | c.1762G>C p.D588H | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- SFPQ | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- THSD7B | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- TTN | c.55714G>C p.D18572H (on ENST00000591111; = p.D11148H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/347 reads (5%) | PolyPhen benign (0.444); called by muse, mutect2
- UMAD1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- USP9X | c.7553C>T p.S2518L | Missense Mutation (SNP) | VAF 20/373 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.53); called by muse, mutect2
- COL20A1 | c.93C>T p.L31= | Silent (SNP) | VAF 22/396 reads (6%) | catalogued as rs750394568, COSV100489752; called by muse, mutect2
- IPO8 | c.2622G>A p.Q874= | Silent (SNP) | VAF 92/262 reads (35%) | called by muse, mutect2, varscan2
- KCNA5 | c.495C>T p.F165= | Silent (SNP) | VAF 44/960 reads (5%) | catalogued as rs1251090692, COSV52905159; called by muse, mutect2
- KLHDC7A | c.156C>T p.G52= | Silent (SNP) | VAF 179/554 reads (32%) | called by muse, mutect2
- KRT5 | c.1188G>C p.L396= | Silent (SNP) | VAF 18/341 reads (5%) | catalogued as COSV52860256; called by muse, mutect2
- NCBP2L | c.375C>T p.R125= | Silent (SNP) | VAF 48/275 reads (17%) | catalogued as rs773993102, COSV64943883; called by muse, mutect2, varscan2
- PREX2 | c.4470C>T p.I1490= | Silent (SNP) | VAF 36/518 reads (7%) | called by muse, mutect2
- SLC7A9 | c.1290C>T p.I430= | Silent (SNP) | VAF 30/514 reads (6%) | catalogued as rs771287087; called by muse, mutect2
- SLC9A4 | c.1359C>G p.V453= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- STK36 | c.2566C>T p.L856= | Silent (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- TGFB3 | c.159C>T p.L53= | Silent (SNP) | VAF 19/597 reads (3%) | called by muse, mutect2
- TTN | c.20895G>A p.E6965= (on ENST00000591111; = p.E6038= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/333 reads (5%) | catalogued as COSV60197793; called by muse, mutect2
- MLIP | c.613-10918C>T | Intron (SNP) | VAF 30/487 reads (6%) | called by muse, mutect2
- STAT5B | c.*357C>T | 3'UTR (SNP) | VAF 62/389 reads (16%) | called by muse, mutect2, varscan2
